Somatic mutation profile of tumor specimen TCGA-61-2613-01A (aliquot TCGA-61-2613-01A-01W-1092-09) from TCGA case TCGA-61-2613, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 73.3 years (26,779 days).
Specimen TCGA-61-2613-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8e790163-5010-47a3-9e2e-76ca78174de0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-2613-11A (Solid Tissue Normal), aliquot TCGA-61-2613-11A-01W-1092-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8bcfce38-e7c9-4d6a-b948-bf3d50f025cc

The open-access MAF lists 78 somatic variants for this specimen: 63 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 48, Silent 15, Nonsense Mutation 5, In Frame Del 4, Splice Site 4, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 191/233 reads (82%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs876660754, CM070299, COSV52676535, COSV52677795, COSV52695723, COSV52823354; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAM15 | c.1609C>T p.P537S | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs896682633, COSV55130045; called by muse, mutect2, varscan2
- AKR1C3 | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 32/459 reads (7%) | catalogued as COSV101003185, COSV65911302; called by muse, mutect2
- AMBP | c.171G>T p.K57N | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV54325754; called by muse, mutect2, varscan2
- AQP1 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.238); catalogued as rs760999882, COSV61268236; called by muse, mutect2, varscan2
- ART3 | c.584A>G p.N195S | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as COSV61916157; called by muse, mutect2, varscan2
- CA9 | c.388C>A p.H130N | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV65676569; called by muse, mutect2, varscan2
- CALCR | c.1239+2T>G p.X413_splice (on ENST00000649521 / NM_001164737.2; = p.X397_splice on NM_001742.4) | Splice Site (SNP) | VAF 101/268 reads (38%) | catalogued as COSV64012150; called by muse, varscan2
- CCDC120 | c.248G>T p.R83L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV64515808; called by muse, mutect2, varscan2
- CCDC62 | c.977+1G>A p.X326_splice | Splice Site (SNP) | VAF 96/144 reads (67%) | catalogued as rs771967288, COSV53434837; called by muse, mutect2, varscan2
- CEP164 | c.1318-2A>G p.X440_splice | Splice Site (SNP) | VAF 51/155 reads (33%) | catalogued as COSV54046548; called by muse, mutect2, varscan2
- CIAO2A | c.445C>G p.R149G | Missense Mutation (SNP) | VAF 86/290 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.972); catalogued as rs746761595, COSV55539373; called by muse, mutect2, varscan2
- CNKSR1 | c.75C>A p.D25E | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.079); catalogued as COSV100836802; called by muse, mutect2, varscan2
- CNKSR1 | c.76T>C p.Y26H | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.614); catalogued as COSV100836803; called by muse, mutect2, varscan2
- COL3A1 | c.1585G>T p.V529F | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV100483795; called by mutect2, varscan2
- CPT1A | c.580A>T p.M194L | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV55761408; called by muse, mutect2, varscan2
- CSMD2 | c.1592G>T p.R531L | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0.169); catalogued as COSV53965954, COSV99592122; called by muse, mutect2, varscan2
- CSMD3 | c.4402A>G p.I1468V (on ENST00000297405 / NM_001363185.1; = p.I1364V on NM_052900.3) | Missense Mutation (SNP) | VAF 26/209 reads (12%) | SIFT tolerated (0.81); PolyPhen benign (0.217); catalogued as rs1242308548, COSV52326796; called by muse, mutect2, varscan2
- EDIL3 | c.850T>A p.S284T | Missense Mutation (SNP) | VAF 127/370 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.636); catalogued as COSV56922419; called by muse, mutect2, varscan2
- EPHA3 | c.911G>C p.C304S | Missense Mutation (SNP) | VAF 65/241 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV60728643; called by muse, mutect2, varscan2
- ERBB4 | c.908C>T p.S303F | Missense Mutation (SNP) | VAF 69/242 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1484791833, COSV53499709, COSV53525659; called by muse, mutect2, varscan2
- FANCA | c.3382C>A p.Q1128K | Missense Mutation (SNP) | VAF 41/62 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as CM1010319, CM970498, COSV59798735; called by muse, mutect2, varscan2
- FOXP2 | c.1441G>T p.D481Y | Missense Mutation (SNP) | VAF 64/193 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV100647573, COSV63494413; called by muse, mutect2, varscan2
- GPR119 | c.598C>T p.R200* | Nonsense Mutation (SNP) | VAF 25/105 reads (24%) | catalogued as rs201745966, COSV52275291; called by muse, mutect2, varscan2
- GRIA2 | c.263T>A p.I88N | Missense Mutation (SNP) | VAF 179/497 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52406984; called by muse, mutect2, varscan2
- GRIA4 | c.1305A>T p.E435D | Missense Mutation (SNP) | VAF 83/204 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV56920802; called by muse, mutect2, varscan2
- GTF3C3 | c.2209G>T p.V737F | Missense Mutation (SNP) | VAF 146/382 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV55834704; called by muse, mutect2, varscan2
- HK2 | c.926T>C p.I309T | Missense Mutation (SNP) | VAF 26/428 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV99309632; called by muse, mutect2
- IQGAP2 | c.901G>T p.V301F | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV57183079; called by muse, mutect2, varscan2
- KMT5A | c.428C>T p.S143L | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs1298609620, COSV57864983; called by muse, mutect2, varscan2
- KRT6B | c.412G>T p.V138F | Missense Mutation (SNP) | VAF 157/694 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52886761; called by muse, mutect2, varscan2
- LARS1 | c.1718G>C p.C573S (on ENST00000394434 / NM_020117.11; = p.C546S on NM_016460.3) | Missense Mutation (SNP) | VAF 133/446 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV50990607; called by muse, mutect2, varscan2
- LDB2 | c.689G>A p.C230Y | Missense Mutation (SNP) | VAF 89/162 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58783465; called by mutect2, varscan2
- MAGI1 | c.455_457del p.G152del | In Frame Del (DEL) | VAF 36/121 reads (30%) | catalogued as rs1211877929; called by mutect2, pindel, varscan2
- MASTL | c.2009C>G p.P670R | Missense Mutation (SNP) | VAF 56/176 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60912698; called by muse, mutect2, varscan2
- MFAP2 | c.111C>G p.H37Q | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.001); catalogued as COSV65004121; called by muse, mutect2, varscan2
- NASP | c.1916T>C p.I639T | Missense Mutation (SNP) | VAF 75/267 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as rs546656039, COSV59648706; called by muse, mutect2, varscan2
- NCR1 | c.324G>C p.E108D | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as COSV52558657; called by muse, mutect2, varscan2
- NF1 | c.4107C>A p.Y1369* | Nonsense Mutation (SNP) | VAF 19/80 reads (24%) | catalogued as CM143397, COSV62214782; called by muse, mutect2, varscan2
- NF2 | c.863C>G p.S288* | Nonsense Mutation (SNP) | VAF 82/155 reads (53%) | catalogued as COSV58523216; called by muse, mutect2, varscan2
- NUP155 | c.2511A>C p.L837F (on ENST00000231498 / NM_153485.3; = p.L778F on NM_004298.4) | Missense Mutation (SNP) | VAF 30/181 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs780853280, COSV51534986; called by muse, mutect2, varscan2
- OR5H1 | c.676T>A p.L226I | Missense Mutation (SNP) | VAF 175/464 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63403548; called by muse, mutect2, varscan2
- OR8K1 | c.732C>G p.F244L | Missense Mutation (SNP) | VAF 58/202 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.766); catalogued as COSV54404702; called by muse, mutect2, varscan2
- PCDHB13 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 73/236 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.975); catalogued as rs782053306, COSV53394300; called by muse, varscan2
- PLEKHA1 | c.341C>G p.T114R | Missense Mutation (SNP) | VAF 27/219 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64570446; called by muse, mutect2, varscan2
- RRM1 | c.1205C>T p.T402I | Missense Mutation (SNP) | VAF 65/126 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.785); catalogued as COSV56166344; called by muse, mutect2, varscan2
- RRP12 | c.1034C>G p.A345G | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.505); catalogued as COSV59671675; called by muse, mutect2, varscan2
- SETBP1 | c.3182T>C p.M1061T | Missense Mutation (SNP) | VAF 122/178 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV56337566; called by muse, mutect2, varscan2
- SLAMF7 | c.376+2T>A p.X126_splice | Splice Site (SNP) | VAF 14/138 reads (10%) | catalogued as COSV63564166; called by muse, mutect2, varscan2
- SLC23A2 | c.1063G>A p.V355M | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs760070455, COSV57780162; called by muse, mutect2, varscan2
- SLC25A13 | c.1090T>C p.S364P | Missense Mutation (SNP) | VAF 18/249 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.366); catalogued as COSV99674287; called by muse, mutect2
- SLC6A15 | c.1244A>T p.E415V | Missense Mutation (SNP) | VAF 14/217 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.678); catalogued as COSV99881633; called by muse, mutect2
- STEAP1 | c.600C>T p.V200= | Splice Region (SNP) | VAF 162/524 reads (31%) | catalogued as COSV51883119; called by muse, mutect2, varscan2
- TEAD4 | c.1224G>T p.L408F | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100622196; called by muse, mutect2
- USP7 | c.3164A>G p.E1055G | Missense Mutation (SNP) | VAF 66/125 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV61213665, COSV61217648; called by muse, mutect2, varscan2
- ZNF335 | c.1868G>A p.C623Y | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59820439; called by muse, mutect2, varscan2
- ZNF648 | c.184A>G p.T62A | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); catalogued as COSV60572868; called by muse, mutect2, varscan2
- ZNF80 | c.489C>A p.C163* | Nonsense Mutation (SNP) | VAF 64/181 reads (35%) | catalogued as COSV57362668; called by muse, mutect2, varscan2
- ACOT7 | c.729_740del p.F244_G247del (on ENST00000377855 / NM_181864.3; = p.F234_G237del on NM_007274.4) | In Frame Del (DEL) | VAF 34/82 reads (41%) | called by mutect2, varscan2
- CAMTA1 | c.4060_4077del p.R1354_M1359del | In Frame Del (DEL) | VAF 22/69 reads (32%) | called by mutect2, pindel, varscan2
- GDF2 | c.644T>A p.V215D | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- NUP50 | c.563_578del p.K188Ifs*2 | Frame Shift Del (DEL) | VAF 32/94 reads (34%) | called by pindel, varscan2
- OPA1 | c.1010_1027del p.Y337_H342del (on ENST00000361510 / NM_130837.3; = p.Y282_H287del on NM_015560.3) | In Frame Del (DEL) | VAF 45/158 reads (28%) | called by mutect2, pindel, varscan2
- ACADM | c.765G>A p.V255= | Silent (SNP) | VAF 154/306 reads (50%) | catalogued as COSV57714721; called by muse, mutect2, varscan2
- DLX3 | c.759C>T p.H253= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as rs369379332; called by muse, mutect2
- DNMBP | c.1383C>T p.P461= | Silent (SNP) | VAF 51/139 reads (37%) | catalogued as COSV60633476; called by muse, mutect2, varscan2
- ENTPD6 | c.1059C>T p.H353= | Silent (SNP) | VAF 34/87 reads (39%) | catalogued as rs375550123, COSV61751872; called by muse, mutect2, varscan2
- FCGBP | c.7758G>T p.L2586= | Silent (SNP) | VAF 40/231 reads (17%) | called by muse, mutect2, varscan2
- GRK5 | c.1032C>G p.G344= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV64867980; called by muse, mutect2, varscan2
- HMCN1 | c.15342G>C p.G5114= | Silent (SNP) | VAF 67/174 reads (39%) | catalogued as COSV54943593; called by muse, mutect2, varscan2
- ITGAM | c.1524T>G p.A508= (on ENST00000648685 / NM_001145808.2; = p.A507= on NM_000632.4) | Silent (SNP) | VAF 146/321 reads (45%) | catalogued as COSV54942946; called by muse, mutect2, varscan2
- LIG3 | c.606G>A p.L202= | Silent (SNP) | VAF 11/103 reads (11%) | catalogued as rs1297539332, COSV52011518; called by muse, mutect2, varscan2
- MSH6 | c.2346C>G p.L782= | Silent (SNP) | VAF 82/220 reads (37%) | catalogued as COSV52288683; called by muse, mutect2, varscan2
- NAT2 | c.306C>T p.S102= | Silent (SNP) | VAF 70/126 reads (56%) | catalogued as COSV54063198; called by muse, mutect2, varscan2
- PDE8B | c.627G>C p.V209= | Silent (SNP) | VAF 55/147 reads (37%) | catalogued as COSV53746126; called by muse, mutect2, varscan2
- PIK3AP1 | c.1722G>A p.E574= | Silent (SNP) | VAF 46/377 reads (12%) | catalogued as COSV59537603; called by muse, mutect2, varscan2
- RUNX1T1 | c.396C>A p.T132= (on ENST00000265814 / NM_001198628.1; = p.T105= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 96/259 reads (37%) | catalogued as COSV56163859; called by muse, mutect2, varscan2
- USP7 | c.2988C>T p.H996= | Silent (SNP) | VAF 50/86 reads (58%) | catalogued as rs754178330, COSV61217654; called by muse, mutect2, varscan2
